Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A2NA, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A2NA-01A (Primary Tumor).

ADDENDA:
Addendum

Collection Date:

MOLECULAR ANATOMIC PATHOLOGY TESTING:

(thyroid right mid lobe papillary carcinoma 1.5 cm):

- A. **BRAF** mutation IDENTIFIED
B. Mutations in **NRAS61**, **HRAS61**, **KRAS12/13** and **RET/PTC1** and **RET/PTC3** rearrangements NOT identified.

NOTE:

Nucleic acids were extracted in the amount sufficient for testing.

FINAL DIAGNOSIS:

PART 1: THYROID, TOTAL THYROIDECTOMY (31 GRAMS) -

- A. PAPILLARY THYROID CARCINOMA: MULTIFOCAL, BILATERAL, AT LEAST 7 FOCI (RANGE: less than 0.1 TO 1.5 CM)
B. LARGEST FOCUS: RIGHT MID LOBE, CONVENTIONAL TYPE WITH FOCAL TALL CELL FEATURES (see comment).
1. ANGIOLYMPHATIC INVASION PRESENT.
2. MICROSCOPIC EXTRATHYROIDAL EXTENSION PRESENT.
3. CARCINOMA FOCALLY EXTENDS TO THE SURGICAL MARGIN.
4. PATHOLOGIC STAGE: pT3 N0.
C. ONE (1) LYMPH NODE, NO TUMOR PRESENT (0/1).
D. ONCOCYTIC FOLLICULAR (HÜRTLE CELL) ADENOMA (2.5 CM), RIGHT LOBE.
E. CHRONIC LYMPHOCYTIC THYROIDITIS AND NODULAR HYPERPLASIA.

PART 2: CENTRAL COMPARTMENT CONTENTS, EXCISION -

- A. ONE (1) NORMOCYLLULAR PARATHYROID GLAND.
B. UNREMARKABLE THYMIC TISSUE
C. NO LYMPH NODES PRESENT.
D. TISSUE ENTIRELY SUBMITTED FOR HISTOLOGIC EVALUATION.

COMMENT:

Molecular studies will be performed and the results will be reported as an addendum.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY THYROID TUMORS

SPECIMEN TYPE: Total Thyroidectomy
TUMOR SITE: Right Lobe, Left Lobe
TUMOR FOCALITY: Multifocal
TUMOR SIZE (largest nodule): Greatest Dimension: 1.5 cm
HISTOLOGIC TYPE*: Papillary carcinoma
PRIMARY TUMOR (pT): pT3
REGIONAL LYMPH NODES (pN): pN0

DISTANT METASTASIS (pM): Number of regional lymph nodes examined: 1
EXTRATHYROIDAL EXTENSION: Not applicable
Present

MARGINS: Extent: Minimal
LYMPH-VASCULAR INVASION: Margin(s) involved by carcinoma
ADDITIONAL PATHOLOGIC FINDINGS: Not identified
Adenoma
Thyroiditis

ICD-0-3
carcinoma, papillary, thyroid
8260/3
Site: thyroid, NOS C73.9
8/18/11

Source: NCI Genomic Data Commons file 9975cd39-160d-4dbe-8fb7-cd14ba550202 (TCGA-BJ-A2NA.24BC880A-E148-4D78-8C33-5F8FB59258E5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).